Somatic mutation profile of tumor specimen MP2PRT-PAPGZI-TBP1-A (aliquot MP2PRT-PAPGZI-TBP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PAPGZI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,463 days).
Specimen MP2PRT-PAPGZI-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88d5824a-6010-4089-9ea1-6c508d83184d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPGZI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPGZI-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e79e28c9-658f-4d41-bfb3-56794fff3205

The open-access MAF lists 11 somatic variants for this specimen: 4 protein-altering or splice-affecting, 7 silent.
By variant classification: Silent 7, Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C8A | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 36/422 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs530776774, COSV100776515; called by muse, mutect2
- SHROOM4 | c.1778G>A p.R593H | Missense Mutation (SNP) | VAF 55/413 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782490910; called by muse, mutect2, varscan2
- TNFRSF11A | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 56/650 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as rs777022699, COSV54022316; called by muse, mutect2
- DMBT1 | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 24/948 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2
- ARSF | c.1710A>T p.P570= | Silent (SNP) | VAF 17/294 reads (6%) | called by muse, mutect2
- CDHR2 | c.2304C>T p.Y768= | Silent (SNP) | VAF 66/690 reads (10%) | catalogued as rs565179867, COSV56142447, COSV99991052; called by muse, mutect2
- CDRT15L2 | c.642G>T p.L214= | Silent (SNP) | VAF 37/411 reads (9%) | called by muse, mutect2
- PADI3 | c.231C>T p.I77= | Silent (SNP) | VAF 13/409 reads (3%) | catalogued as rs372035647; called by muse, mutect2
- RAP1GAP | c.1707G>A p.S569= | Silent (SNP) | VAF 63/546 reads (12%) | catalogued as rs774473606; called by muse, mutect2, varscan2
- SLC34A2 | c.954G>A p.S318= | Silent (SNP) | VAF 40/464 reads (9%) | catalogued as rs754995617; called by muse, mutect2
- ZNF835 | c.921G>A p.T307= | Silent (SNP) | VAF 65/677 reads (10%) | catalogued as rs763855200; called by muse, mutect2, varscan2
